Gene-level copy-number profile of specimen HCM-SANG-0281-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0281-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0281-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba450586-669b-48fc-9573-552d9be33c03.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0281-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/55c7d582-7110-40e9-939e-015b3da68701

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 720; copy number 2: 29,097; copy number 3: 23,922; copy number 4: 3,242; copy number 5: 536; copy number 6: 696; copy number 7: 162; copy number 8: 20; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:795,606–850,986, 2 genes (within-gene range 0–2): ZDHHC11, SPCS2P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,415 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–14,409, 1 gene, copy number 21: DDX11L1.
- chr1:143,811,359–143,825,837, 1 gene, copy number 8: AC239798.1.
- chr1:143,874,793–143,883,575, 1 gene, copy number 5 (within-gene range 4–5): FCGR1CP.
- chr8:39,451,045–39,522,852, 1 gene, copy number 7: ADAM3A.
- chr15:101,903,154–101,903,204, 1 gene, copy number 5: AC140725.2.
- chr17:22,519,617–22,706,703, 14 genes, copy number 7: MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr20:87,250–16,053,197, 286 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 5 (within-gene range 1–5): MACROD2-AS1.
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
